Somatic mutation profile of tumor specimen TCGA-BJ-A191-01A (aliquot TCGA-BJ-A191-01A-11D-A13W-08) from TCGA case TCGA-BJ-A191, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 49.7 years (18,162 days).
Specimen TCGA-BJ-A191-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 305c357a-3e0c-4e97-9cbe-8129ccaecb06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A191-10A (Blood Derived Normal), aliquot TCGA-BJ-A191-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c22f50c1-abf6-4439-97de-a4075d825e7c

The open-access MAF lists 23 somatic variants for this specimen: 16 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 13, Silent 7, Frame Shift Ins 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NUP93 | c.43C>T p.Q15* | Nonsense Mutation (SNP) | VAF 36/120 reads (30%) | hotspot (GDC flag); catalogued as COSV57428872, COSV57434100; called by muse, mutect2, varscan2
- ABHD4 | c.734G>A p.C245Y | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53530790; called by muse, mutect2, varscan2
- ACAD10 | c.2029C>G p.R677G | Missense Mutation (SNP) | VAF 62/120 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs368355800, COSV58155479; called by muse, mutect2, varscan2
- BTBD7 | c.1561C>G p.R521G | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100597990, COSV58285585; called by muse, mutect2, varscan2
- FREM1 | c.5261A>G p.E1754G | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66530918; called by muse, mutect2, varscan2
- LSAMP | c.661A>G p.I221V | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV61312951; called by muse, mutect2, varscan2
- NPBWR2 | c.216G>T p.R72S | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV63900656; called by muse, mutect2, varscan2
- NPEPPS | c.183C>G p.I61M | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.537); catalogued as rs769086867, COSV59105961; called by muse, mutect2, varscan2
- PDCD1 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.171); catalogued as COSV57691476, COSV57692488; called by muse, mutect2, varscan2
- PLXDC2 | c.1078G>C p.D360H | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV65909293; called by muse, mutect2, varscan2
- RIC3 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.087); catalogued as COSV58305309; called by muse, varscan2
- RIMS2 | c.4291C>T p.R1431C (on ENST00000666250 / NM_001348490.2; = p.R1002C on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763285258, COSV51660936; called by muse, mutect2, varscan2
- SARAF | c.604C>A p.P202T | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); catalogued as COSV56358547; called by muse, mutect2, varscan2
- TECPR2 | c.287C>T p.T96I | Missense Mutation (SNP) | VAF 57/98 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63974581; called by muse, mutect2, varscan2
- CLVS1 | c.678_705del p.W227Sfs*20 | Frame Shift Del (DEL) | VAF 25/106 reads (24%) | called by mutect2, pindel
- NDUFS5 | c.189_190insTA p.V64* | Frame Shift Ins (INS) | VAF 57/124 reads (46%) | called by mutect2, pindel*, varscan2
- ALPK2 | c.2835C>G p.L945= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as COSV64497655; called by muse, varscan2
- CCL13 | c.36C>G p.L12= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV56775768; called by muse, mutect2, varscan2
- CELF5 | c.810G>C p.V270= | Silent (SNP) | VAF 71/197 reads (36%) | catalogued as COSV53015504; called by muse, mutect2, varscan2
- DAAM1 | c.510C>T p.Y170= | Silent (SNP) | VAF 63/137 reads (46%) | catalogued as rs1231745080, COSV62840072; called by muse, mutect2, varscan2
- NCOR1 | c.3405C>T p.T1135= | Silent (SNP) | VAF 31/63 reads (49%) | catalogued as rs752964070, COSV51959498; called by muse, mutect2, varscan2
- STON2 | c.1794C>T p.F598= (on ENST00000649389 / NM_001366849.2; = p.F541= on NM_001256430.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/120 reads (42%) | catalogued as COSV50856296, COSV99964916; called by muse, mutect2, varscan2
- TSC22D1 | c.366C>G p.S122= | Silent (SNP) | VAF 134/299 reads (45%) | catalogued as COSV71776467; called by muse, mutect2, varscan2
